Somatic mutation profile of tumor specimen MMRF_2258_1_BM_CD138pos (aliquot MMRF_2258_1_BM_CD138pos_T1_KHS5U_L09516) from MMRF case MMRF_2258, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 74.5 years (27,200 days).
Specimen MMRF_2258_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) de752f13-4e83-46fc-ab1f-1cab3829c094.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2258_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2258_1_PB_Whole_C3_KHS5U_L09517; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8eb31781-e9b9-4042-b098-fc48a49820a3

The open-access MAF lists 107 somatic variants for this specimen: 31 protein-altering or splice-affecting, 24 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 24, 3'UTR 24, Intron 11, 5'Flank 10, 5'UTR 5, 3'Flank 1, Splice Site 1, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CFAP61 | c.2971G>A p.E991K | Missense Mutation (SNP) | VAF 93/197 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.526); catalogued as rs114584531; called by muse, mutect2, varscan2
- CPNE8 | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100504119; called by muse, mutect2, varscan2
- DISP2 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 104/165 reads (63%) | SIFT tolerated (0.13); PolyPhen benign (0.152); catalogued as rs1206362826, COSV51123319; called by muse, mutect2, varscan2
- GPR39 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 32/364 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as rs750566310, COSV100258105; called by muse, mutect2
- HAPLN4 | c.884C>T p.A295V | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.5); catalogued as rs374049916; called by muse, mutect2, varscan2
- IGKV5-2 | c.28T>C p.F10L | Missense Mutation (SNP) | VAF 41/53 reads (77%) | SIFT tolerated (1); PolyPhen possibly damaging (0.494); catalogued as rs759159553; called by muse, mutect2, varscan2
- IGKV5-2 | c.86C>T p.A29V | Missense Mutation (SNP) | VAF 85/104 reads (82%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as rs1156298882; called by muse, mutect2, varscan2
- IGLV3-1 | c.213G>C p.K71N | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs181926700; called by muse, varscan2
- MDM4 | c.1217C>T p.T406I | Missense Mutation (SNP) | VAF 54/229 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs4252741; called by muse, mutect2, varscan2
- NR2E3 | c.1000C>T p.R334W | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs371402963, CM056661; called by muse, mutect2, varscan2
- PBRM1 | c.1414C>T p.R472* | Nonsense Mutation (SNP) | VAF 41/105 reads (39%) | catalogued as COSV56262370; called by muse, mutect2, varscan2
- SALL3 | c.3860T>G p.F1287C | Missense Mutation (SNP) | VAF 141/415 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101609996; called by muse, mutect2, varscan2
- SLFN14 | c.2552C>G p.P851R | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs375612069; called by muse, mutect2, varscan2
- TAS2R41 | c.241G>A p.G81S | Missense Mutation (SNP) | VAF 22/159 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs761627851, COSV101281465; called by muse, mutect2, varscan2
- TMPRSS11A | c.829G>T p.A277S | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV58359379; called by muse, mutect2, varscan2
- CACNA1D | c.2704G>C p.A902P (on ENST00000350061 / NM_001128840.3; = p.A922P on NM_000720.4) | Missense Mutation (SNP) | VAF 113/185 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- CAMKV | c.107G>A p.C36Y | Missense Mutation (SNP) | VAF 94/373 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- CNTN5 | c.2296A>C p.I766L | Missense Mutation (SNP) | VAF 51/205 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CXCR6 | c.1018T>G p.F340V | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH5 | c.11818G>T p.D3940Y | Missense Mutation (SNP) | VAF 27/128 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DUSP2 | c.730+1G>C p.X244_splice | Splice Site (SNP) | VAF 94/218 reads (43%) | called by muse, mutect2, varscan2
- IGHV1-69 | c.170G>C p.R57P | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.233); called by muse, mutect2
- IGHV2-70D | c.158T>A p.M53K | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.396); called by muse, varscan2
- LHX6 | c.319C>A p.Q107K (on ENST00000373755 / NM_001242334.2; = p.Q136K on NM_014368.5) | Missense Mutation (SNP) | VAF 140/232 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- PLPPR3 | c.345C>G p.S115R | Missense Mutation (SNP) | VAF 27/282 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.84); called by muse, mutect2
- SCRT1 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- TMPRSS11A | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 48/136 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UPP1 | c.449G>A p.G150D | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF875 | c.1598G>A p.G533D | Missense Mutation (SNP) | VAF 50/301 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- ZNF99 | c.1564T>C p.S522P | Missense Mutation (SNP) | VAF 10/119 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2
- ACKR2 | c.235C>A p.R79= | Silent (SNP) | VAF 43/189 reads (23%) | called by muse, mutect2, varscan2
- CCDC138 | c.1683G>A p.T561= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as rs772517834, COSV99719091; called by muse, mutect2, varscan2
- CES4A | c.45G>A p.A15= | Silent (SNP) | VAF 30/95 reads (32%) | catalogued as rs375489966; called by muse, mutect2, varscan2
- DSTYK | c.1083C>T p.A361= | Silent (SNP) | VAF 34/72 reads (47%) | called by muse, mutect2, varscan2
- ELFN2 | c.810C>T p.D270= | Silent (SNP) | VAF 44/144 reads (31%) | catalogued as rs202059228, COSV101297607; called by muse, mutect2, varscan2
- ERCC4 | c.1668G>A p.P556= | Silent (SNP) | VAF 148/220 reads (67%) | catalogued as rs759296999; called by muse, mutect2, varscan2
- FAM135B | c.144C>T p.I48= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs751821996, COSV50539735; called by muse, mutect2, varscan2
- FARP1 | c.1504C>T p.L502= | Silent (SNP) | VAF 51/146 reads (35%) | called by muse, mutect2, varscan2
- HPSE | c.831G>A p.K277= | Silent (SNP) | VAF 79/188 reads (42%) | called by muse, mutect2, varscan2
- HTRA3 | c.573C>T p.H191= | Silent (SNP) | VAF 23/58 reads (40%) | catalogued as rs370723674; called by muse, mutect2, varscan2
- IGHV2-70 | c.306A>G p.T102= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as rs377122389; called by muse, varscan2
- IGHV2-70D | c.339G>C p.T113= | Silent (SNP) | VAF 18/49 reads (37%) | called by muse, varscan2
- IGHV2-70D | c.306A>G p.T102= | Silent (SNP) | VAF 17/80 reads (21%) | called by muse, varscan2
- IGLV3-1 | c.222A>T p.S74= | Silent (SNP) | VAF 40/100 reads (40%) | catalogued as rs185368174; called by muse, varscan2
- IRX2 | c.462C>A p.T154= | Silent (SNP) | VAF 43/70 reads (61%) | called by muse, mutect2, varscan2
- MFSD10 | c.1290G>A p.T430= | Silent (SNP) | VAF 13/161 reads (8%) | catalogued as rs748576806; called by muse, mutect2
- ODF4 | c.654C>T p.A218= | Silent (SNP) | VAF 26/67 reads (39%) | catalogued as rs199979906; called by muse, mutect2, varscan2
- OR2M7 | c.75C>T p.T25= | Silent (SNP) | VAF 71/209 reads (34%) | catalogued as rs1425114486; called by muse, mutect2, varscan2
- OR2Z1 | c.126C>T p.N42= | Silent (SNP) | VAF 8/205 reads (4%) | called by muse, mutect2
- PTPRD | c.1599G>A p.L533= | Silent (SNP) | VAF 40/93 reads (43%) | called by muse, mutect2, varscan2
- RAB35 | c.417C>G p.A139= | Silent (SNP) | VAF 102/241 reads (42%) | called by muse, mutect2, varscan2
- TSPAN2 | c.639G>A p.A213= | Silent (SNP) | VAF 143/345 reads (41%) | catalogued as rs370287808; called by muse, mutect2, varscan2
- WDR4 | c.1095C>T p.F365= | Silent (SNP) | VAF 32/88 reads (36%) | catalogued as rs530476358, COSV57733554; called by muse, mutect2, varscan2
- ZNF43 | c.663G>A p.K221= | Silent (SNP) | VAF 22/137 reads (16%) | called by muse, mutect2, varscan2
- ACTB | c.-27-130C>T | Intron (SNP) | VAF 40/118 reads (34%) | catalogued as rs551830507; called by muse, mutect2, varscan2
- APBB2 | c.*3950T>C | 3'UTR (SNP) | VAF 24/66 reads (36%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122020924 T>G | 5'Flank (SNP) | VAF 47/123 reads (38%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021074 G>C | 5'Flank (SNP) | VAF 34/112 reads (30%) | called by muse, varscan2
- BCL7A | chr12:122021150 A>G | 5'Flank (SNP) | VAF 44/134 reads (33%) | catalogued as COSV55847065, COSV55851768; called by muse, varscan2
- BCL7A | chr12:122021260 C>G | 5'Flank (SNP) | VAF 50/115 reads (43%) | catalogued as COSV55846296; called by muse, varscan2
- BCL7A | chr12:122021350 C>A | 5'Flank (SNP) | VAF 32/98 reads (33%) | called by muse, varscan2
- BCL7A | chr12:122021459 A>G | 5'Flank (SNP) | VAF 38/102 reads (37%) | called by muse, varscan2
- BTAF1 | c.990+87A>T | Intron (SNP) | VAF 14/42 reads (33%) | called by muse, varscan2
- C8orf89 | c.*8C>T | 3'UTR (SNP) | VAF 12/148 reads (8%) | catalogued as rs1014050965; called by muse, mutect2
- CCNC | chr6:99569018 A>G | 5'Flank (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2, varscan2
- DGKI | chr7:137847001 A>C | 5'Flank (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- EBF3 | c.-124G>A | 5'UTR (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2, varscan2
- EHD1 | c.*465C>G | 3'UTR (SNP) | VAF 126/207 reads (61%) | called by muse, mutect2, varscan2
- EPYC | c.*294A>T | 3'UTR (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- EPYC | c.*293T>A | 3'UTR (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- ERMN | chr2:157327587 C>T | 5'Flank (SNP) | VAF 104/316 reads (33%) | called by muse, mutect2, varscan2
- EXOC5 | c.*4519C>T | 3'UTR (SNP) | VAF 28/59 reads (47%) | catalogued as rs1033150111; called by muse, mutect2, varscan2
- FLRT2 | c.*4436G>A | 3'UTR (SNP) | VAF 40/88 reads (45%) | called by muse, mutect2, varscan2
- GPR158 | c.*35C>T | 3'UTR (SNP) | VAF 102/361 reads (28%) | catalogued as rs758215270, COSV100892971; called by muse, mutect2, varscan2
- HMGA2 | c.282+452A>G | Intron (SNP) | VAF 25/65 reads (38%) | called by muse, mutect2, varscan2
- ISCU | c.418+540C>T | Intron (SNP) | VAF 34/550 reads (6%) | called by muse, mutect2
- ITPR1 | c.*1139A>G | 3'UTR (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- ITPR1 | c.*1225A>G | 3'UTR (SNP) | VAF 31/90 reads (34%) | called by muse, mutect2, varscan2
- JPT2 | c.*696A>G | 3'UTR (SNP) | VAF 39/134 reads (29%) | called by muse, mutect2, varscan2
- KIAA0825 | c.970+400T>C | Intron (SNP) | VAF 14/38 reads (37%) | catalogued as rs1395005546; called by muse, mutect2, varscan2
- KRTAP1-5 | c.*152C>T | 3'UTR (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2
- LAMA3 | c.-78G>A | 5'UTR (SNP) | VAF 7/13 reads (54%) | called by muse, varscan2
- MME | c.*973T>C | 3'UTR (SNP) | VAF 77/112 reads (69%) | called by muse, mutect2, varscan2
- MSL3 | c.382+69A>G | Intron (SNP) | VAF 14/25 reads (56%) | called by muse, mutect2, varscan2
- MSR1 | c.*368C>G | 3'UTR (SNP) | VAF 17/55 reads (31%) | called by muse, mutect2, varscan2
- NDUFA3 | c.11-88G>A | Intron (SNP) | VAF 61/121 reads (50%) | called by muse, mutect2, varscan2
- NT5C1B | chr2:18563055 T>G | 3'Flank (SNP) | VAF 23/57 reads (40%) | called by muse, mutect2, varscan2
- PAPSS2 | c.-143C>T | 5'UTR (SNP) | VAF 39/90 reads (43%) | called by muse, mutect2, varscan2
- PCDHA10 | c.2388+5037C>T | Intron (SNP) | VAF 4/46 reads (9%) | catalogued as rs966575223; called by muse, mutect2
- PHC1P1 | n.1972C>T | RNA (SNP) | VAF 56/158 reads (35%) | catalogued as rs1161727418; called by muse, mutect2, varscan2
- PHKG2 | c.271+34G>A | Intron (SNP) | VAF 69/102 reads (68%) | catalogued as rs765120698, COSV100079365; called by muse, mutect2, varscan2
- PLA2G4E | c.*1136G>A | 3'UTR (SNP) | VAF 54/387 reads (14%) | catalogued as rs965871130; called by muse, mutect2, varscan2
- PLEKHH3 | c.-9C>T | 5'UTR (SNP) | VAF 40/75 reads (53%) | catalogued as rs1380052514; called by muse, mutect2, varscan2
- POLR2M | c.*2470A>G | 3'UTR (SNP) | VAF 79/471 reads (17%) | called by muse, mutect2, varscan2
- PRTG | c.*1381A>C | 3'UTR (SNP) | VAF 23/170 reads (14%) | catalogued as rs376050106; called by muse, mutect2, varscan2
- PTEN | c.-366_-363del | 5'UTR (DEL) | VAF 4/30 reads (13%) | catalogued as rs1365232630; called by mutect2, pindel
- RNASEH2C | c.*1569A>G | 3'UTR (SNP) | VAF 58/177 reads (33%) | catalogued as rs1015225859; called by muse, mutect2, varscan2
- SEL1L3 | chr4:25863607 C>T | 5'Flank (SNP) | VAF 45/84 reads (54%) | called by muse, mutect2, varscan2
- SERTM1 | c.*1204G>A | 3'UTR (SNP) | VAF 18/40 reads (45%) | catalogued as rs1205002927; called by muse, varscan2
- SLC44A1 | c.*424C>T | 3'UTR (SNP) | VAF 15/67 reads (22%) | called by muse, mutect2, varscan2
- SMAD2 | c.*3623T>G | 3'UTR (SNP) | VAF 55/141 reads (39%) | called by muse, mutect2, varscan2
- STAU1 | c.*929del | 3'UTR (DEL) | VAF 4/26 reads (15%) | called by mutect2, pindel
- TRAM2 | c.*992G>T | 3'UTR (SNP) | VAF 29/84 reads (35%) | called by muse, mutect2, varscan2
- UBASH3A | c.354+558G>T | Intron (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- USH2A | c.*903A>G | 3'UTR (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
- VPS37B | c.111+6644C>G | Intron (SNP) | VAF 23/82 reads (28%) | called by muse, mutect2, varscan2
